Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6681, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6681-01A (Primary Tumor).

[page 1 of 6]
[illegible]

Clinical Diagnosis & History:
[REDACTED] female with rectal cancer. Endometrial thickening and adnexal mass with rectal cancer.

- 1: Endometrial curettings
- 2: Sigmoid and rectum; resection
- 3: Segment three liver resection
- 4: Left tube and ovary
- 5: Right tube and ovary
- 6: Re-excision of sigmoid colon
- 7: Distal margin
- 8: Proximal margin

1. Endometriosis; curettage [REDACTED]
- Scant benign strips of atrophic endometrium and endocervical mucosa.
- Abundant mucus.
2. Sigmoid and rectum; resection:
- Tumor Type:
- Adenocarcinoma with mucinous features (<50% mucinous component)
- Histologic Grade:
- Moderately differentiated
- Tumor Location:
- Rectosigmoid
- Tumor Size:
- Length is 7.0 cm
- Width is 4.0 cm
- Maximal thickness is 1.3 cm
- Tumor Budding:
- Focal
- Increased Tumor Infiltrating Lymphocytes:
- Absent
- Precursor Lesions:
- Not identified
- Deepest Tumor Invasion:
- Subserosal adipose tissue and/or mesenteric fat
- Tumor is noted very close (<0.1 cm) from the serosal surface
- Gross Tumor Perforation:

** Continued on next page **

[page 2 of 6]
Not identified

Lymphovascular Invasion:

Suspected

Large Venous Invasion:

Suspected

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 7

Total number examined: 24

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N2a (Metastasis in 4-6 regional lymph nodes)

3. Liver, segment three; resection:

- Metastatic adenocarcinoma, moderately differentiated, consistent with colorectal primary.

- One tumor nodule, measuring 1.8 x 1.5 x 1.0cm.

- Fibrosis and mucinous changes in 20% of the tumor.

- The hepatic capsule is free of tumor.

- The surgical margins are free of tumor by 1.6cm (gross clearance).

- The non-neoplastic liver shows mild nonspecific changes.

NOTE: Material has been sent for KRAS mutation testing, and will be reported separately.

4. Left fallopian tube and ovary; salpingo-oophorectomy:

- Ovary with adenofibroma.

- Fallopian tube without pathologic abnormalities.

5. Right fallopian tube and ovary; salpingo-oophorectomy:

- Ovary with fibroma.

- Fallopian tube without pathologic abnormalities.

6. Sigmoid colon; re-excision:

- Benign segment of colonic tissue without pathologic abnormalities.

- Four benign lymph nodes (0/4).

7. Colon, distal margin; excision:

- Benign segment of colonic tissue without pathologic abnormalities.

8. Colon, proximal margin; excision:

- Benign segment of colonic tissue without pathologic abnormalities.

** Continued on next page **

[page 3 of 6]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	KRAS	

Gross Description:

1). The specimen is received fresh, labeled "Endometrial curettings". It consists of mostly mucus measuring 2 x 1.5 x 0.3 cm. The specimen is submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control

2). The specimen is received fresh and is labeled "Sigmoid and rectum". It consists of a rectosigmoid colon that measures 25 cm in length and 7 cm in circumference. The serosal surface is smooth. The margins are inked as follows: proximal and radial margins - blue, distal margin black. The specimen is opened to reveal a tumor that is located 11.5 cm from the proximal margin and 3 cm from the distal margin. The tumor measures 7 cm in length and 4 cm in width. Serial sectioning reveals tumor invasion to a depth of 1.3 cm, which is 1.5 cm from the closest radial margin. The remaining mucosa is unremarkable. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin, perpendicular
DM - distal margin, perpendicular
RM - radial margin
T - tumor
U - uninvolved mucosa
LN - lymph nodes
BLN - bisected lymph node

3). The specimen is received fresh and labeled, "Segment three liver resection ". It consists of a liver lobe measuring 8.5 x 6.0 x 3.5 cm. The hepatic capsule is grossly intact with a 1.5 x 0.8 cm raised area. There is a rough hepatic resection margin which is inked black. Serial sectioning at 0.5 cm intervals reveals a white lobular tumor measuring 1.8 x 1.5 x 1.0 cm. The tumor corresponds to raised area on the capsule. There is no gross evidence of tumor within the vessels. There is no gross evidence of tumor within the bile ducts. The closest tumor nodule is 1.6 cm from the inked

** Continued on next page **

[page 4 of 6]
----- Page 4 of 6
surgical resection margin. The remaining hepatic parenchyma is tan-brown and granular. TPS is submitted. Representative sections are submitted to include the remaining tumor.

Summary of sections:

VMvessel from margin

T - tumor

TC - tumor with hepatic capsule

M - margin

U - uninvolved hepatic parenchyma (away from the mass)

4). The specimen is received in formalin, labeled "Left tube and left ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 4.5 cm in length and averages 0.4 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. Cut section through the tube reveals a pinpoint lumen. The attached ovary weighs 4.0 g and measures 3.0 x 2.0 x 1.5 cm. The external surface is white-tan and smooth. Cut section through the ovary reveals 1.5 x 1.5 x 1.3 cm clear fluid filled cyst. Representative sections are submitted.

Summary of sections:

F - fallopian tube

O - ovary

C--cyst

5). The specimen is received in formalin, labeled "Right tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 5.0 cm in length and averages 0.3 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. Cut section through the tube reveals a pinpoint lumen. The attached ovary weighs 2.5 g and measures 2.2 x 1.5 x 1.0 cm. The external surface is tan-white and smooth. Cut section through the ovary reveals a 1.0 x 0.8 x 0.8 cm white-yellow ovoid nodule. Representative sections are submitted.

Summary of sections:

F - fallopian tube

O - ovary

N--nodule

6). The specimen is received in formalin, labeled "Re-excision of sigmoid colon" and consists of a portion of bowel measuring 4.5 cm in length, 5.0 cm in circumference. One aspect of the specimen is stapled close, the opposing aspect is open. The serosa is tan-pink and smooth with attached yellow lobulated adipose tissue. The specimen is opened to reveal tan-brown mucosa with the normal folds. No lesion is grossly identified. Representative sections are submitted. The specimen is submitted for lymph node dissection.

Summary of sections:

** Continued on next page **

[page 5 of 6]
SM--stapled margin
O--open margin
RS--representative sections

7). The specimen is received in formalin, labeled "Distal margin" and consists of a ring of pink tan soft tissue measuring 2.5 x 2.3 x 1.0 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

8). The specimen is received in formalin, labeled "Proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a green plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2.2 x 1.5 x 0.5 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Endometrial curettings

Block	Sect.	Site	PCs
1		FSC	1

Part 2: Sigmoid and rectum; resection

Block	Sect.	Site	PCs
3		DM	3
6		LN	12
1		PM	1
1		RM	1
7		T	7
1		U	1

Part 3: Segment three liver resection

Block	Sect.	Site	PCs
1		M	2

** Continued on next page **

[page 6 of 6]
----- Page 6 of 6

4	T	6
1	TC	1
2	U	4
1	VM	1

Part 4: Left tube and ovary

Block	Sect. Site	PCs
2	C	4
2	F	6
1	O	1

Part 5: Right tube and ovary

Block	Sect. Site	PCs
2	F	4
2	N	3
1	O	2

Part 6: Re-excision of sigmoid colon

Block	Sect. Site	PCs
5	LN	5
1	OM	1
2	RS	4
1	SM	1

Part 7: Distal margin

Block	Sect. Site	PCs
4	U	6

Part 8: Proximal margin

Block	Sect. Site	PCs
2	U	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Endometrial curettings () Benign (Fine)
Permanent diagnosis: Same.

** End of Report **

Source: NCI Genomic Data Commons file c25d718d-6996-4c4c-b4a4-7a88aab3cf29 (TCGA-DC-6681.EE7DDD01-A4E2-4AB8-BED8-B87894171722.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).